Somatic mutation profile of tumor specimen b2d62dca-3741-4d59-92b8-bdcfed (aliquot b2d62dca-3741-4d59-92b8-bdcfed_D6) from CPTAC case 06BR014, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 51.0 years (18,614 days).
Specimen b2d62dca-3741-4d59-92b8-bdcfed: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 143efcc4-0964-42d1-9eb2-5dc3f6a05d72.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 865b5360-f603-4418-9c9f-c182e9 (Blood Derived Normal), aliquot 865b5360-f603-4418-9c9f-c182e9_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3271700-b9c6-404e-a611-94879d40d63e

The open-access MAF lists 23 somatic variants for this specimen: 15 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 4, Intron 2, Nonsense Mutation 2, 5'Flank 1, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 41/113 reads (36%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); catalogued as COSV55885255, COSV55891864; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 57/150 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAP2 | c.2288A>G p.N763S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.236); catalogued as rs373402885, COSV58752130; called by muse, mutect2, varscan2
- ACTBL2 | c.1006C>T p.R336W | Missense Mutation (SNP) | VAF 136/442 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1220404614, COSV70661390; called by muse, mutect2, varscan2
- DMXL1 | c.3863G>A p.S1288N | Missense Mutation (SNP) | VAF 87/263 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.978); catalogued as rs935060198; called by muse, mutect2, varscan2
- MAP3K1 | c.4390-1G>A p.X1464_splice | Splice Site (SNP) | VAF 25/446 reads (6%) | catalogued as COSV101267209, COSV99064032; called by muse, mutect2
- NEB | c.13247C>T p.S4416F | Missense Mutation (SNP) | VAF 51/172 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV50876685, COSV51460148; called by muse, mutect2, varscan2
- TM2D1 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.011); catalogued as rs751636109; called by muse, varscan2
- ZNF611 | c.7C>T p.R3C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs759669986, COSV100160075; called by muse, mutect2, varscan2
- ARHGEF18 | c.3253G>A p.A1085T (on ENST00000359920 / NM_001130955.2; = p.A981T on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAST3 | c.1162G>A p.D388N | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- NEK4 | c.2474dup p.Y825* | Nonsense Mutation (INS) | VAF 14/39 reads (36%) | called by mutect2, pindel, varscan2
- NLRP3 | c.1829T>C p.I610T | Missense Mutation (SNP) | VAF 22/356 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.184); called by muse, mutect2
- OTOG | c.3434C>A p.A1145D | Missense Mutation (SNP) | VAF 75/236 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- SLC17A8 | c.1392T>A p.C464* | Nonsense Mutation (SNP) | VAF 161/467 reads (34%) | called by muse, mutect2, varscan2
- RNF20 | c.1566C>T p.S522= | Silent (SNP) | VAF 18/88 reads (20%) | called by muse, mutect2, varscan2
- STOX2 | c.1425G>A p.Q475= | Silent (SNP) | VAF 115/362 reads (32%) | called by muse, mutect2, varscan2
- TTN | c.16236C>G p.P5412= (on ENST00000591111; = p.P4485= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/70 reads (39%) | catalogued as COSV100626162; called by muse, mutect2, varscan2
- ZNF514 | c.693G>A p.P231= | Silent (SNP) | VAF 16/200 reads (8%) | catalogued as rs145283605; called by muse, mutect2
- CCDC130 | c.-44T>C | 5'UTR (SNP) | VAF 44/139 reads (32%) | called by muse, varscan2
- RABGAP1L | c.2212-11349G>C | Intron (SNP) | VAF 22/77 reads (29%) | called by muse, mutect2, varscan2
- TNPO2 | c.-13-243G>C | Intron (SNP) | VAF 4/35 reads (11%) | catalogued as rs1275333604; called by muse, mutect2
- USP53 | chr4:119212449 G>T | 5'Flank (SNP) | VAF 14/282 reads (5%) | catalogued as rs936224094; called by muse, mutect2
